Somatic mutation profile of tumor specimen 0DV158 from CCDI case PBCLWL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.7 years (2,066 days).
Specimen 0DV158: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab6f5ae4-5a2e-43c9-a748-df06cf902fe4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV14J (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08163fcc-6424-4155-bcf2-38f206f7b821

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERMAP | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 108/462 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HAPLN2 | c.298C>A p.R100S | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGDH | c.2847dup p.N950Qfs*3 | Frame Shift Ins (INS) | VAF 145/543 reads (27%) | called by mutect2, pindel, varscan2
- RPLP1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 140/392 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
